Somatic mutation profile of tumor specimen TARGET-10-PARSKY-09A (aliquot TARGET-10-PARSKY-09A-01D) from TARGET case TARGET-10-PARSKY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,255 days).
Specimen TARGET-10-PARSKY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e248caf-7494-423a-98aa-607144ee3e44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSKY-14A (Bone Marrow Normal), aliquot TARGET-10-PARSKY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f8c892-a24d-4eb9-ab4e-c650fdf44dea

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFHR1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs368662175; called by muse, mutect2, varscan2
- POM121L2 | c.2855C>A p.A952D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1298367701, COSV66277029; called by muse, mutect2, varscan2
- SLC12A5 | c.2639G>A p.R880H (on ENST00000454036 / NM_001134771.2; = p.R857H on NM_020708.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750336750, COSV54793420, COSV54799761; called by muse, mutect2, varscan2
- SORBS2 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200642160; called by muse, mutect2, varscan2
- WDFY4 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs764549050; called by muse, mutect2, varscan2
- NINL | c.1032+1G>T p.X344_splice | Splice Site (SNP) | VAF 64/119 reads (54%) | called by muse, mutect2, varscan2
- PRPF8 | c.5483C>T p.A1828V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- RAPGEF6 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TRANK1 | c.6772T>G p.F2258V | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCC9 | c.2766A>G p.E922= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- INF2 | c.765C>T p.D255= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs758423191; called by muse, mutect2, varscan2
- INSYN2A | c.384A>G p.K128= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- MYOCD | c.2715C>T p.S905= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs147591618; called by muse, mutect2, varscan2
- MIR323A | n.63T>C | RNA (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- NTRK1 | c.1178-112G>A | Intron (SNP) | VAF 59/152 reads (39%) | catalogued as rs41422251; called by muse, mutect2, varscan2
